Surgical pathology report (de-identified scan), TCGA case TCGA-CU-A3KJ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site UNC, specimen TCGA-CU-A3KJ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Review Initial:	12/19/11	12/19/11

Diagnosis:

A: Soft tissue, ureteral margin, biopsy
- No tumor seen

1CB-0-3
carcinoma, urothelial, NOS 8/20/3
Site: bladder, NOS C67.9, W
12/19/11

B: Bladder and prostate, radical cystoprostatectomy

Bladder:

Tumor histologic type: Invasive high grade urothelial carcinoma
with
squamous differentiation

Tumor histologic grade (WHO classification): High grade

Microscopic tumor size (greatest dimension): 6.0 cm by gross
examination

Microscopic extent of invasion: Into perivesicular soft tissues

Tumor site/focality of tumor: Unifocal, left wall, anterior
wall,
trigone and left ureterovesicular junction

Angiolymphatic space invasion: Focal hemangiovascular space
invasion
identified (B8); negative for definite lymphovascular space
invasion

Associated epithelial lesions: Urothelial carcinoma in situ

Ureters: Negative

Histologic assessment of surgical margins:

Ureter, left: Negative

Ureter, right: Negative

Urethra: Negative (FSA1; additional urethral en face section
from main

specimen shows few detached fragments of carcinoma within lumen,
negative for

definite stromal invasion or in situ carcinoma; superseded by
previous negative

frozen section result (FSA1)

[page 2 of 2]
Paravesicular soft tissue: Negative but focally very close, left lateral wall <0.1 cm (B7, B8), right anterior wall <0.1 cm (B9)

Other significant findings: Right and left vas deferens negative, moderate to severe chronic cystitis, benign prostatic hyperplasia, acute and chronic prostatitis, prostate with no evidence of urothelial carcinoma

Lymph nodes: Separately submitted

Size and location of largest lymph node metastasis: N/A

Extracapsular extension: N/A

AJCC PATHOLOGIC TNM STAGE: pT3b pN0

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Prostate:

Tumor histologic type: prostatic adenocarcinoma

Tumor grade (Gleason system): Gleason combined score 6 (3+3)

Approximate percentage of prostate involved by tumor: right lobe 2%

Extent of tumor:

Location of tumor involvement in prostate: right lobe mid to base

Confinement/non-confinement of tumor within the prostatic capsule: confined

Location of extracapsular tumor involvement: not applicable

Type of extracapsular tissue involved within tumor: not applicable

Lymphovascular space invasion: not identified

Seminal vesicles (invasion of muscular wall required): negative

Histologic assessment of surgical margins: negative

Source: NCI Genomic Data Commons file 2c1c867e-ed9f-4e11-8af6-6b9b6c032a7b (TCGA-CU-A3KJ.DC5E6643-868B-40C6-AC67-B594E2F7BFBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).